Somatic mutation profile of tumor specimen 1105255 (aliquot 7316UP-1614-1105255) from CPTAC case C621273, project CPTAC-3 (Colon — Epithelial Neoplasms, NOS). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Colon, NOS.
Specimen 1105255: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8788d15c-374f-45c1-b514-26ce68370f17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105218 (Blood Derived Normal), aliquot 7316UP-1614-1105218; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9d72a68-7d62-48d4-80ed-a3df1c596691

The open-access MAF lists 2,251 somatic variants for this specimen: 1,478 protein-altering or splice-affecting, 455 silent, 318 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,017, Silent 455, Frame Shift Del 260, Intron 158, Frame Shift Ins 82, Nonsense Mutation 55, 3'UTR 50, RNA 40, 5'UTR 37, Splice Region 28, Splice Site 23, 5'Flank 19.

Variants (750 of 2,251; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.1171del p.R391Vfs*12 | Frame Shift Del (DEL) | VAF 101/240 reads (42%) | catalogued as rs751404811, CM045926, CM138787; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 88/268 reads (33%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ARG1 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 85/239 reads (36%) | catalogued as rs104893944, CM993111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 72/186 reads (39%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCND3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 50/131 reads (38%) | hotspot (GDC flag); catalogued as COSV57828583; called by muse, mutect2, varscan2
- CFTR | c.2052del p.K684Nfs*38 | Frame Shift Del (DEL) | VAF 89/304 reads (29%) | catalogued as rs121908746; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL4A5 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886088, CM072961, CM920213, CM960349, COSV60370055; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 98/134 reads (73%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 84/209 reads (40%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- HUWE1 | c.9208C>T p.R3070C | Missense Mutation (SNP) | VAF 171/372 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs886041876, COSV53358976; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 129/290 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KMT2D | c.10740G>A p.Q3580= | Splice Region (SNP) | VAF 74/155 reads (48%) | catalogued as rs398123700; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 90/220 reads (41%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LTBP3 | c.132del p.P45Rfs*25 | Frame Shift Del (DEL) | VAF 69/245 reads (28%) | catalogued as rs1286042594; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LZTR1 | c.27del p.Q10Rfs*15 | Frame Shift Del (DEL) | VAF 105/284 reads (37%) | catalogued as rs587777613; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 104/268 reads (39%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NEB | c.11601+6124C>T | Intron (SNP) | VAF 182/1118 reads (16%) | catalogued as rs1212374733; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAK3 | c.343C>T p.R115* (on ENST00000262836 / NM_001324328.2; = p.R100* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 84/241 reads (35%) | catalogued as rs780775497, COSV53279983; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 37/108 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PKHD1 | c.8162del p.P2721Qfs*14 | Frame Shift Del (DEL) | VAF 96/280 reads (34%) | catalogued as rs1057516775; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.4554dup p.P1519Tfs*18 (on ENST00000303395 / NM_001202435.3; = p.P1508Tfs*18 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 96/319 reads (30%) | catalogued as rs794726825; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC18A2 | c.711dup p.F238Lfs*7 | Frame Shift Ins (INS) | VAF 86/215 reads (40%) | catalogued as rs762879329; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 106/301 reads (35%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 54/134 reads (40%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA12 | c.6960C>T p.T2320= (on ENST00000272895 / NM_173076.3; = p.T2002= on NM_015657.3) | Splice Region (SNP) | VAF 99/285 reads (35%) | catalogued as rs1021345094, COSV55952672; called by muse, mutect2, varscan2
- ABCA13 | c.5198G>A p.R1733H | Missense Mutation (SNP) | VAF 113/263 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs766374669, COSV70028369; called by muse, mutect2, varscan2
- ABCA9 | c.3338G>A p.G1113D | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376048173; called by muse, mutect2, varscan2
- ABCB11 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.961); catalogued as rs199841445, CM117170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCG1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs772470306, COSV59202048; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 273/619 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs201696615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC005324.2 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.367); catalogued as rs1399711435; called by muse, mutect2, varscan2
- AC008397.2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1354369697; called by muse, mutect2, varscan2
- AC231657.3 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV100540123; called by muse, mutect2, varscan2
- ACACB | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs754505331; called by muse, mutect2, varscan2
- ACO1 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs201421085; called by muse, mutect2, varscan2
- ACTL8 | c.290del p.P97Lfs*2 | Frame Shift Del (DEL) | VAF 67/207 reads (32%) | catalogued as rs1557449414; called by mutect2, pindel, varscan2
- ADAMTS20 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253174139, COSV67129756, COSV67135057; called by muse, mutect2, varscan2
- ADAMTS7 | c.3515C>T p.P1172L | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66309397; called by muse, mutect2, varscan2
- ADAMTSL5 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100389280; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs760140619; called by mutect2, varscan2
- ADSS1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 115/290 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200568797; called by muse, mutect2, varscan2
- AEBP1 | c.2841C>A p.N947K | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56261731, COSV99788811; called by muse, mutect2, varscan2
- AEBP2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs982709279; called by muse, mutect2, varscan2
- AFF3 | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760333652, COSV57842263; called by mutect2, varscan2
- AGGF1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 85/242 reads (35%) | catalogued as rs376959475; called by muse, mutect2, varscan2
- AGRN | c.3589G>A p.G1197S | Missense Mutation (SNP) | VAF 256/632 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs886460165; called by muse, mutect2
- AHNAK | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs540814813; called by muse, mutect2, varscan2
- AHNAK2 | c.13787C>T p.T4596M | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1407036271, COSV60921135; called by muse, mutect2, varscan2
- AJAP1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); catalogued as COSV65450662, COSV65451766; called by muse, mutect2, varscan2
- AK5 | c.1549C>T p.R517C (on ENST00000354567 / NM_174858.3; = p.R491C on NM_012093.4) | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs144951885; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP11 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs949131444; called by muse, mutect2, varscan2
- AKR7A3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 16/234 reads (7%) | catalogued as rs774727965, COSV64389805; called by muse, mutect2
- AL133500.1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.23); catalogued as rs368985442; called by muse, mutect2, varscan2
- ALAD | c.683del p.P228Lfs*24 | Frame Shift Del (DEL) | VAF 161/510 reads (32%) | catalogued as rs1564369378; called by mutect2, pindel, varscan2
- ALG12 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 144/385 reads (37%) | PolyPhen possibly damaging (0.882); catalogued as rs769555808; called by muse, mutect2, varscan2
- AMIGO2 | c.1271G>A p.C424Y | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56973924; called by muse, mutect2, varscan2
- AMPD2 | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 209/490 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56647784; called by muse, mutect2, varscan2
- ANGEL2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs190621865, COSV100853948; called by muse, mutect2, varscan2
- ANK1 | c.1717del p.L573Cfs*64 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as CD014448; called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1018081322; called by muse, mutect2, varscan2
- ANKRD36 | c.2407A>T p.S803C | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV70741297; called by muse, mutect2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 86/182 reads (47%) | catalogued as rs753570186; called by mutect2, varscan2
- ANKRD62 | c.1439del p.K480Sfs*5 | Frame Shift Del (DEL) | VAF 33/83 reads (40%) | catalogued as rs774510795; called by mutect2, varscan2
- ANKS1A | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs764196187; called by muse, varscan2
- AP1M2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs781427984, COSV51569707; called by muse, mutect2, varscan2
- APAF1 | c.698G>A p.R233H (on ENST00000551964 / NM_181861.2; = p.R222H on NM_001160.3) | Missense Mutation (SNP) | VAF 125/324 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs141157255; called by muse, mutect2, varscan2
- APBA2 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 113/472 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68788804; called by muse, mutect2, varscan2
- APBA3 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs746107677; called by muse, mutect2, varscan2
- APOBR | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.522); catalogued as rs1226606108; called by muse, mutect2, varscan2
- ARHGAP39 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs948752387; called by muse, mutect2, varscan2
- ARHGEF1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782497331, COSV61526594; called by muse, mutect2, varscan2
- ARHGEF12 | c.4229G>A p.R1410H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs202128571; called by muse, mutect2, varscan2
- ARHGEF17 | c.6127G>A p.G2043S | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs368547430; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 80/240 reads (33%) | catalogued as COSV61389445; called by pindel, varscan2
- ARID1B | c.1243del p.A415Pfs*15 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as rs1417035592; called by mutect2, pindel, varscan2
- ARID2 | c.2554C>T p.Q852* | Nonsense Mutation (SNP) | VAF 62/173 reads (36%) | catalogued as rs925229355; called by muse, mutect2, varscan2
- ARMH4 | c.1955A>T p.E652V | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1298492864; called by muse, mutect2
- ARRB1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs776740350, COSV63576778; called by muse, mutect2, varscan2
- ARRB2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1247288395, COSV52619383; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 74/159 reads (47%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSK | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.623); catalogued as rs374366998; called by muse, mutect2, varscan2
- ASB18 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749930126, COSV58236116; called by muse, mutect2
- ASXL1 | c.2462A>G p.D821G | Missense Mutation (SNP) | VAF 157/363 reads (43%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs780896078; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs746676748; called by mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP1A2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759097524, COSV100767806, COSV100768062; called by muse, mutect2, varscan2
- ATXN7L2 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV60203941; called by muse, mutect2, varscan2
- B3GAT1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 130/312 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs965181801; called by muse, mutect2, varscan2
- B3GNTL1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762230226, COSV57946545; called by muse, mutect2
- BAG2 | c.222C>T p.D74= | Splice Region (SNP) | VAF 44/85 reads (52%) | catalogued as rs756825488, COSV65786799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCKDK | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.409); catalogued as rs374568685; called by muse, mutect2, varscan2
- BCL7C | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53062710; called by muse, mutect2, varscan2
- BCL9L | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs149904706; called by muse, varscan2
- BCLAF1 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs749172270, COSV50357499, COSV99219398; called by muse, mutect2, varscan2
- BDNF | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 170/425 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs750030464, COSV100151992, COSV59234276; called by muse, mutect2, varscan2
- BEND7 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs767454294, COSV61987407; called by muse, mutect2, varscan2
- BICDL2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV54157477; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2042A>C p.D681A | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100863735; called by mutect2, varscan2
- BIVM-ERCC5 | c.2899G>A p.A967T | Missense Mutation (SNP) | VAF 157/560 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs775996769, COSV63245635; called by muse, mutect2, varscan2
- BLVRA | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as rs1315965538; called by muse, mutect2, varscan2
- BRAF | c.2405C>T p.A802V (on ENST00000288602 / NM_001374244.1; = p.A762V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs775889922, COSV56115442, COSV56368837; called by muse, varscan2
- BRD7 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs150539401; called by muse, mutect2, varscan2
- BRWD3 | c.4573G>A p.G1525S | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs771173711, COSV64752792; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 50/155 reads (32%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- BUB3 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs1445770507; called by muse, mutect2, varscan2
- C3orf49 | c.620del p.K207Rfs*14 | Frame Shift Del (DEL) | VAF 53/140 reads (38%) | catalogued as rs1466063805; called by mutect2, varscan2
- C4orf54 | c.4640del p.P1547Qfs*70 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | catalogued as rs763082793; called by mutect2, pindel, varscan2
- C6orf163 | c.174dup p.E59Rfs*19 | Frame Shift Ins (INS) | VAF 35/95 reads (37%) | catalogued as rs1184371126; called by mutect2, pindel, varscan2
- C8A | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 162/419 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs149254627; called by muse, mutect2, varscan2
- CACNG3 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50064973; called by muse, mutect2, varscan2
- CALHM2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 132/351 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1278152148; called by muse, mutect2, varscan2
- CARF | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs1236943005; called by muse, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CATSPER1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs137878849; called by muse, mutect2, varscan2
- CAVIN3 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 178/349 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.106); catalogued as rs1475063142; called by muse, mutect2, varscan2
- CCDC115 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs752919660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC166 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1262427244; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC184 | c.511dup p.D171Gfs*44 | Frame Shift Ins (INS) | VAF 26/74 reads (35%) | catalogued as rs755249564; called by mutect2, varscan2
- CCDC58 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV52246521; called by muse, mutect2, varscan2
- CCDC85A | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.352); catalogued as rs757348777; called by muse, mutect2, varscan2
- CCDC97 | c.547dup p.L183Pfs*4 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as rs865828858; called by mutect2, pindel
- CCNY | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1473002179; called by muse, mutect2, varscan2
- CCR5 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201179081; called by muse, mutect2, varscan2
- CD248 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as rs751114440, COSV60936700; called by muse, mutect2, varscan2
- CDC42BPA | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs146827361; called by muse, mutect2, varscan2
- CDH13 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs376202554; called by muse, mutect2, varscan2
- CDK8 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV67419126; called by muse, mutect2, varscan2
- CDNF | c.493dup p.T165Nfs*2 | Frame Shift Ins (INS) | VAF 74/254 reads (29%) | catalogued as rs1245164692; called by mutect2, pindel, varscan2
- CDRT15L2 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.302); catalogued as rs1257262707; called by muse, mutect2, varscan2
- CELF2 | c.1477C>T p.R493C (on ENST00000416382 / NM_001025077.3; = p.R506C on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59976730; called by muse, mutect2, varscan2
- CELSR1 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 134/314 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs147651051; called by muse, mutect2, varscan2
- CELSR3 | c.1392dup p.N465Qfs*25 | Frame Shift Ins (INS) | VAF 63/166 reads (38%) | catalogued as rs753657474; called by mutect2, pindel, varscan2
- CEMIP | c.1086+2T>G p.X362_splice | Splice Site (SNP) | VAF 254/456 reads (56%) | catalogued as COSV99586769; called by muse, mutect2, varscan2
- CERT1 | c.766C>T p.R256C (on ENST00000405807 / NM_001130105.1; = p.R128C on NM_005713.3) | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1214748516, COSV54657657; called by muse, mutect2, varscan2
- CFAP46 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs536559191, COSV100886078; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs1274191949; called by mutect2, varscan2
- CFAP91 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs766913590, COSV56342306; called by muse, mutect2, varscan2
- CHAF1A | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs758651234; called by muse, mutect2, varscan2
- CHD5 | c.5444C>T p.T1815M | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs573215215, COSV52409305; called by muse, mutect2, varscan2
- CHD7 | c.6193C>T p.R2065C | Missense Mutation (SNP) | VAF 162/400 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM117687, CM133772, CM147861, COSV101418091; called by muse, mutect2, varscan2
- CHRNA7 | c.1412G>A p.C471Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1396553385; called by mutect2, varscan2
- CHRNB4 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs760548392, COSV55717198; called by muse, mutect2, varscan2
- CKB | c.431dup p.H145Afs*77 | Frame Shift Ins (INS) | VAF 124/339 reads (37%) | catalogued as rs749928387; called by mutect2, pindel, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 74/175 reads (42%) | catalogued as rs761731080; called by mutect2, varscan2
- CLEC4A | c.236dup p.T80Dfs*35 | Frame Shift Ins (INS) | VAF 32/123 reads (26%) | catalogued as rs1182229842; called by mutect2, varscan2
- CLIC5 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.338); catalogued as COSV51754904; called by muse, mutect2, varscan2
- CLPTM1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV61613318; called by muse, mutect2, varscan2
- CLRN2 | c.435C>T p.G145= | Splice Region (SNP) | VAF 53/119 reads (45%) | catalogued as rs994079252; called by muse, mutect2, varscan2
- CLSTN2 | c.2211C>T p.Y737= | Splice Region (SNP) | VAF 30/71 reads (42%) | catalogued as rs148317543; called by muse, mutect2, varscan2
- CMKLR1 | c.746G>A p.R249H (on ENST00000312143 / NM_001142344.2; = p.R247H on NM_004072.3) | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760204829, COSV100379365; called by muse, mutect2, varscan2
- CNNM1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 152/313 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1231680009; called by muse, mutect2, varscan2
- CNTN1 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs374471716; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP4 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | catalogued as rs1013311455, COSV56671148; called by muse, mutect2, varscan2
- COL12A1 | c.5303G>A p.S1768N | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs371310137; called by muse, mutect2, varscan2
- COL4A5 | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60358956; called by muse, mutect2, varscan2
- COL5A1 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs530442560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.2153G>C p.G718A | Missense Mutation (SNP) | VAF 24/560 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV104425761; called by muse, mutect2
- COL6A5 | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs751443853, COSV55195783; called by muse, mutect2, varscan2
- COL7A1 | c.8506G>A p.V2836I | Missense Mutation (SNP) | VAF 181/485 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1246764789; called by muse, mutect2, varscan2
- COL7A1 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 192/468 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs757643340, COSV60395303; called by muse, mutect2, varscan2
- CORO2B | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 96/388 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs748303629; called by mutect2, varscan2
- COX4I2 | c.1-2A>G p.X1_splice | Splice Site (SNP) | VAF 133/325 reads (41%) | catalogued as rs1192963566; called by muse, mutect2, varscan2
- CPLANE1 | c.17G>T p.G6V (on ENST00000425232; = p.G78V on NM_023073.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554117507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPPED1 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.35); catalogued as COSV55497505; called by muse, mutect2, varscan2
- CPZ | c.1104G>A p.M368I (on ENST00000360986 / NM_001014447.3; = p.M357I on NM_003652.3) | Missense Mutation (SNP) | VAF 90/184 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs866318508; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 228/600 reads (38%) | catalogued as rs747832403; called by mutect2, varscan2
- CRACR2A | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 105/246 reads (43%) | catalogued as COSV61543578; called by muse, mutect2, varscan2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 189/447 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CREB3L2 | c.851A>T p.K284I | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1403332874; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYBG2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as rs369844437; called by muse, mutect2, varscan2
- CTU1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 209/544 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70292656; called by muse, mutect2, varscan2
- CYB5R2 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55085436; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 48/161 reads (30%) | catalogued as rs756254049; called by mutect2, varscan2
- CYP39A1 | c.270dup p.V91Sfs*4 | Frame Shift Ins (INS) | VAF 49/175 reads (28%) | catalogued as rs1225765844; called by mutect2, pindel, varscan2
- DBR1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as rs868835210, COSV53428908; called by muse, mutect2
- DCAF8 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 139/321 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs752089736, COSV58783348; called by muse, mutect2, varscan2
- DCAF8L1 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as COSV71595330; called by muse, mutect2, varscan2
- DDX20 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV63831144; called by muse, varscan2
- DDX4 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as rs771635664, COSV100737632; called by muse, mutect2, varscan2
- DDX60 | c.4843G>T p.G1615C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV101190231; called by muse, mutect2, varscan2
- DGKQ | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 153/343 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1180775609; called by muse, mutect2, varscan2
- DHX34 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201148024, COSV60895322; called by muse, mutect2, varscan2
- DIP2A | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as rs369917913; called by muse, mutect2, varscan2
- DLC1 | c.1820C>T p.A607V (on ENST00000276297 / NM_001348081.2; = p.A170V on NM_006094.5) | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs929788084, COSV52326811; called by muse, mutect2, varscan2
- DLGAP1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759947491; called by muse, mutect2, varscan2
- DLGAP4 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs192489219; called by muse, mutect2, varscan2
- DMBX1 | c.740del p.G247Vfs*15 | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | catalogued as COSV63601642, COSV63602450; called by mutect2, pindel
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 56/254 reads (22%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH10 | c.5963G>A p.R1988H (on ENST00000409039; = p.R1927H on NM_207437.3) | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs370827875; called by muse, mutect2, varscan2
- DNAH10 | c.8210C>T p.T2737M (on ENST00000409039; = p.T2676M on NM_207437.3) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs756405690, COSV68989039; called by muse, mutect2, varscan2
- DNAH11 | c.11678C>T p.T3893M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs763843747, COSV60974905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT3A | c.176del p.P59Rfs*13 | Frame Shift Del (DEL) | VAF 48/106 reads (45%) | catalogued as COSV53040261; called by mutect2, varscan2
- DOCK11 | c.3290A>G p.Q1097R | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); catalogued as COSV52234969; called by muse, mutect2, varscan2
- DPP10 | c.1312dup p.I438Nfs*7 | Frame Shift Ins (INS) | VAF 16/79 reads (20%) | catalogued as rs752853990; called by mutect2, pindel, varscan2
- DRC7 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs778999719; called by muse, mutect2, varscan2
- DSEL | c.628dup p.I210Nfs*6 | Frame Shift Ins (INS) | VAF 71/220 reads (32%) | catalogued as rs1215181888; called by mutect2, pindel, varscan2
- DSG3 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933771; called by muse, mutect2, varscan2
- DUOX2 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 300/468 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs750639157, COSV66535311; called by muse, mutect2, varscan2
- DUSP22 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 94/379 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV60527529; called by muse, mutect2, varscan2
- DYRK3 | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100895664; called by muse, mutect2, varscan2
- E2F7 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 79/233 reads (34%) | catalogued as rs780614837, COSV59739397; called by muse, mutect2, varscan2
- E4F1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs765015745, COSV57040679, COSV57041008; called by muse, mutect2, varscan2
- ECPAS | c.4681G>A p.G1561R | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1367783816; called by muse, mutect2, varscan2
- EIF2B2 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 177/433 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs765712931; called by muse, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 56/180 reads (31%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EMILIN2 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs201283611; called by muse, mutect2, varscan2
- EML4 | c.1775C>T p.T592I | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs1188101154; called by muse, mutect2, varscan2
- EPG5 | c.5704dup p.Y1902Lfs*2 | Frame Shift Ins (INS) | VAF 42/120 reads (35%) | catalogued as rs760768451; called by mutect2, varscan2
- EPHA6 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs780254423, COSV67598252; called by muse, mutect2, varscan2
- ERBB2 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54071889; called by muse, mutect2
- ETS1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 134/321 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60096717; called by muse, mutect2, varscan2
- EVX1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.613); catalogued as rs1444751704; called by muse, mutect2
- EXO1 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 116/306 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs750940919, COSV62218506; called by muse, mutect2, varscan2
- F8 | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM054679, CM1314155; called by muse, mutect2, varscan2
- FAM117B | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 203/519 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57419272; called by muse, mutect2, varscan2
- FAM135B | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52716667, COSV52755853; called by muse, mutect2, varscan2
- FAM155A | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 147/525 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs202062814, COSV65586584; called by muse, mutect2, varscan2
- FAM186A | c.2261dup p.V755Gfs*16 | Frame Shift Ins (INS) | VAF 52/157 reads (33%) | catalogued as rs1325556099; called by mutect2, varscan2
- FAM187A | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1453848416; called by muse, mutect2
- FAM189B | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 123/304 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.905); catalogued as rs1240159655, COSV63219355; called by muse, mutect2, varscan2
- FAM193B | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs373410343; called by muse, mutect2, varscan2
- FAM20A | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 154/373 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1335379646; called by muse, mutect2, varscan2
- FAM83H | c.1289C>G p.S430W | Missense Mutation (SNP) | VAF 31/401 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as CM1111030, COSV101186932, COSV66353541; called by muse, mutect2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 64/146 reads (44%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 158/346 reads (46%) | catalogued as rs747011618; called by mutect2, varscan2
- FAT3 | c.8239C>T p.R2747W | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs200763217; called by muse, mutect2, varscan2
- FAT4 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs759309740, COSV67885713; called by muse, mutect2, varscan2
- FBXL7 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 129/390 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1401076306; called by muse, mutect2, varscan2
- FBXW12 | c.1363A>G p.S455G | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs201317090; called by muse, mutect2, varscan2
- FCGBP | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 158/1254 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.397); catalogued as rs1337616242; called by muse, mutect2, varscan2
- FDFT1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs559977336; called by muse, mutect2, varscan2
- FERD3L | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs866406481, COSV51762348; called by muse, mutect2, varscan2
- FGF2 | c.17del p.G6Vfs*4 | Frame Shift Del (DEL) | VAF 25/60 reads (42%) | catalogued as rs776164719; called by mutect2, pindel, varscan2
- FHDC1 | c.2505del p.V836Sfs*25 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | catalogued as COSV52600528; called by mutect2, pindel, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FITM1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 125/295 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as rs900868217; called by muse, mutect2, varscan2
- FKBP1C | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 153/368 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as rs1178283539; called by muse, mutect2, varscan2
- FLNA | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 163/416 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM162870; called by muse, mutect2, varscan2
- FLT4 | c.89dup p.T31Dfs*15 | Frame Shift Ins (INS) | VAF 124/311 reads (40%) | catalogued as rs755445139; called by mutect2, varscan2
- FN1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 141/353 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777763524, COSV100115678; called by muse, mutect2, varscan2
- FOXF2 | c.96del p.A33Pfs*89 | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | catalogued as COSV99453578; called by pindel, varscan2
- FOXL1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 223/533 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57213590; called by muse, mutect2, varscan2
- FOXN3 | c.1162G>A p.E388K (on ENST00000261302; = p.E366K on NM_005197.4) | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs772625675, COSV54305153; called by muse, varscan2
- FRAS1 | c.5783A>G p.H1928R | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as rs1471365312, COSV99356005; called by muse, mutect2, varscan2
- FREM3 | c.6398G>T p.S2133I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as rs965688625; called by muse, mutect2, varscan2
- FRMPD1 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.165); catalogued as rs749927300; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 69/150 reads (46%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSIP2 | c.8038del p.T2680Hfs*3 | Frame Shift Del (DEL) | VAF 54/164 reads (33%) | catalogued as rs755234663; called by mutect2, varscan2
- FSIP2 | c.20133A>T p.K6711N | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); catalogued as rs754643795; called by muse, varscan2
- FUT1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 137/386 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.891); catalogued as rs150995632; called by muse, mutect2, varscan2
- FZD2 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1339183245, COSV59527929; called by muse, mutect2, varscan2
- FZD9 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.005); catalogued as rs782003819; called by muse, mutect2, varscan2
- GAD1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as rs1238959934, COSV60151582; called by muse, mutect2, varscan2
- GAD1 | c.755del p.X252_splice | Splice Site (DEL) | VAF 193/546 reads (35%) | catalogued as COSV60152140; called by mutect2, pindel, varscan2
- GALNT14 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100204024; called by muse, mutect2, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 52/155 reads (34%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GALNT8 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs769100382, COSV52897296, COSV52900639; called by muse, mutect2, varscan2
- GART | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs757263290; called by muse, mutect2, varscan2
- GAS6 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750814570, COSV59853160; called by muse, mutect2, varscan2
- GASK1B | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56709593; called by muse, mutect2, varscan2
- GATA2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.434); catalogued as rs1413920280; called by muse, mutect2, varscan2
- GATAD2A | c.1094del p.P365Hfs*9 | Frame Shift Del (DEL) | VAF 100/282 reads (35%) | catalogued as rs35804366; called by mutect2, pindel, varscan2
- GCC1 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1335179556; called by muse, mutect2, varscan2
- GDF1 | c.742del p.L248Wfs*27 | Frame Shift Del (DEL) | VAF 37/109 reads (34%) | catalogued as rs938987727; called by mutect2, pindel, varscan2
- GDPD2 | c.108C>T p.C36= | Splice Region (SNP) | VAF 17/175 reads (10%) | catalogued as rs781034905; called by muse, mutect2
- GFM1 | c.836T>C p.L279S | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99963191; called by muse, mutect2, varscan2
- GFRA1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 145/344 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs754335579; called by muse, mutect2, varscan2
- GLB1 | c.2006dup p.N669Kfs*53 | Frame Shift Ins (INS) | VAF 98/248 reads (40%) | catalogued as rs759633494; called by mutect2, varscan2
- GLI2 | c.4100G>A p.R1367H (on ENST00000361492 / NM_001374353.1; = p.R1384H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs763852684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI3 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 188/446 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270096533; called by muse, mutect2, varscan2
- GLIS1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs369266481, COSV56550362; called by muse, mutect2, varscan2
- GMEB2 | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV56609013; called by muse, mutect2, varscan2
- GMIP | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs200618177; called by muse, mutect2, varscan2
- GNAL | c.854C>T p.A285V (on ENST00000269162 / NM_001142339.3; = p.A362V on NM_182978.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV52334956; called by muse, mutect2, varscan2
- GNAS | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs587778390, COSV58345123, COSV58347881; ClinVar: not provided; called by muse, mutect2, varscan2
- GNAZ | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1365180134, COSV50739124; called by muse, mutect2, varscan2
- GOLGA6C | c.2036del p.P679Rfs*? | Frame Shift Del (DEL) | VAF 148/364 reads (41%) | catalogued as rs773221176, COSV100316303; called by mutect2, pindel, varscan2
- GPR18 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 106/427 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs748648382; called by muse, mutect2, varscan2
- GRIN3B | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as rs79866475; called by muse, mutect2, varscan2
- GRM5 | c.3320C>T p.T1107M (on ENST00000305447 / NM_001143831.2; = p.T1075M on NM_000842.4) | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.966); catalogued as rs546269389; called by muse, mutect2, varscan2
- GTF2IRD2B | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs1243072857; called by mutect2, varscan2
- GTPBP3 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs140393384; called by muse, mutect2, varscan2
- H1-0 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs773049853, COSV50649873; called by muse, mutect2, varscan2
- HDAC6 | c.3532G>A p.D1178N | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs782174981, COSV100491256; called by muse, mutect2, varscan2
- HDHD3 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs747591014, COSV53056601; called by muse, mutect2, varscan2
- HEATR5B | c.6214dup p.*2072Lfs*18 | Frame Shift Ins (INS) | VAF 23/74 reads (31%) | catalogued as rs1315552549; called by mutect2, varscan2
- HELLS | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371792267; called by muse, mutect2, varscan2
- HELZ2 | c.6727C>T p.R2243C (on ENST00000467148 / NM_001037335.2; = p.R1674C on NM_033405.3) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636547; called by muse, mutect2, varscan2
- HERC2 | c.9089G>A p.S3030N | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.929); catalogued as rs201973387; called by muse, mutect2, varscan2
- HIGD1A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs565556493, COSV58414573, COSV58414971; called by muse, mutect2, varscan2
- HK3 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs745623940; called by muse, mutect2, varscan2
- HK3 | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 110/251 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs754406639; called by muse, mutect2, varscan2
- HLA-B | c.343+1G>A p.X115_splice | Splice Site (SNP) | VAF 30/216 reads (14%) | catalogued as rs1168937188, COSV69520345, COSV69521733; called by muse, varscan2
- HLA-DQB1 | c.535del p.I180Lfs*12 | Frame Shift Del (DEL) | VAF 37/83 reads (45%) | catalogued as rs751976368; called by mutect2, pindel, varscan2
- HLTF | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs372129397; called by muse, mutect2, varscan2
- HMCN2 | c.5063A>G p.E1688G | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs548738574; called by muse, mutect2, varscan2
- HMCN2 | c.5926C>T p.R1976W | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.535); catalogued as rs577965469; called by muse, mutect2
- HMGN2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.974); catalogued as COSV52577298, COSV52578084; called by muse, mutect2, varscan2
- HOXD13 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 161/404 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763149315, COSV66832773; called by muse, mutect2, varscan2
- HRH2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 141/309 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199533; called by muse, mutect2, varscan2
- HS3ST1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as COSV50024246; called by muse, mutect2, varscan2
- HS6ST2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1428531182; called by muse, mutect2, varscan2
- HSPBP1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355096967; called by muse, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 50/140 reads (36%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE1 | c.6476C>T p.A2159V | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs375797140; called by muse, mutect2, varscan2
- IFT140 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68488099; called by muse, mutect2, varscan2
- IGSF10 | c.5642G>A p.G1881D | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477022137; called by muse, mutect2, varscan2
- IL11 | c.540del p.L181Cfs*3 | Frame Shift Del (DEL) | VAF 95/253 reads (38%) | catalogued as COSV99214838; called by mutect2, pindel, varscan2
- IL18R1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV52125413; called by muse, mutect2, varscan2
- IL1B | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 136/363 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1312684514; called by muse, mutect2, varscan2
- ILVBL | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as rs1263662509; called by muse, mutect2, varscan2
- INHBA | c.802del p.E268Kfs*91 | Frame Shift Del (DEL) | VAF 59/180 reads (33%) | catalogued as COSV54219689, COSV54219996; called by mutect2, pindel, varscan2
- INO80E | c.531del p.D178Tfs*8 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs1339809802; called by mutect2, pindel, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPP4A | c.2653C>T p.R885C (on ENST00000074304 / NM_001134224.1; = p.R846C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777173666, COSV50785099, COSV99302563; called by muse, mutect2, varscan2
- INTS5 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.55); catalogued as rs756443040; called by muse, mutect2, varscan2
- IPO9 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1157160147, COSV64234766; called by muse, mutect2, varscan2
- IQCK | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs545479453; called by muse, mutect2
- IQSEC2 | c.1232C>T p.A411V (on ENST00000642864 / NM_001111125.3; = p.A206V on NM_015075.2) | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.005); catalogued as COSV64728474; called by muse, mutect2
- IQSEC3 | c.565del p.V189Cfs*109 | Frame Shift Del (DEL) | VAF 60/153 reads (39%) | catalogued as COSV58283925; called by mutect2, pindel, varscan2
- IRF4 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66704532, COSV66705920; called by muse, mutect2, varscan2
- IRS4 | c.1952del p.G651Efs*23 | Frame Shift Del (DEL) | VAF 153/478 reads (32%) | catalogued as COSV64532818; called by mutect2, pindel, varscan2
- IRX1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs976102129; called by muse, mutect2, varscan2
- IRX2 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 150/395 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs775015331; called by muse, mutect2, varscan2
- IRX6 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51860590; called by muse, mutect2, varscan2
- ITIH1 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 66/145 reads (46%) | catalogued as rs757375117, COSV56255433; called by muse, mutect2, varscan2
- ITK | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 103/260 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs780522355, COSV68435348, COSV68435382; called by muse, mutect2, varscan2
- ITPKB | c.179dup p.A61Sfs*24 | Frame Shift Ins (INS) | VAF 72/204 reads (35%) | catalogued as rs1240487177; called by mutect2, pindel, varscan2
- JADE2 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs763968541, COSV50911820; called by muse, mutect2
- JMY | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as rs1349756551, COSV68660803, COSV68662092; called by muse, mutect2
- JRK | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs375362605, COSV101401029; called by muse, mutect2, varscan2
- JRK | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1283928169, COSV70630291; called by muse, mutect2, varscan2
- KBTBD13 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 125/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs775442274; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 112/304 reads (37%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNH8 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs747522897; called by muse, mutect2
- KCNJ4 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs776902829; called by muse, mutect2, varscan2
- KCP | c.4228C>T p.R1410* (on ENST00000620378; = p.R1534* on NM_001366122.1) | Nonsense Mutation (SNP) | VAF 12/160 reads (8%) | catalogued as rs370254255; called by muse, mutect2
- KIAA1109 | c.14227C>T p.R4743C | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767116983, COSV52662892; called by muse, varscan2
- KIF4B | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 124/346 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs374852803; called by muse, mutect2, varscan2
- KLHDC3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.943); catalogued as rs962420421; called by muse, mutect2, varscan2
- KLHDC7A | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 161/390 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs185356965; called by muse, mutect2, varscan2
- KLHDC9 | c.387dup p.A130Rfs*5 | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | catalogued as rs761803466; called by mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 28/129 reads (22%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL10 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs782043692; called by muse, mutect2, varscan2
- KLHL42 | c.1321_1325del p.N441Dfs*6 | Frame Shift Del (DEL) | VAF 88/329 reads (27%) | catalogued as rs774224353; called by mutect2, pindel, varscan2
- KMT2C | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1319381877, COSV100065922; called by muse, mutect2
- KMT2D | c.16086G>T p.K5362N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as CD159008, COSV99982182; called by muse, mutect2, varscan2
- KNL1 | c.5884C>T p.L1962F (on ENST00000346991 / NM_170589.5; = p.L1936F on NM_144508.5) | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs939715110, COSV61151691; called by muse, mutect2, varscan2
- KRT23 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 97/218 reads (44%) | catalogued as rs773310417; called by muse, mutect2, varscan2
- KRT75 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768683532; called by muse, mutect2, varscan2
- KRTAP10-11 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 181/453 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1555940261; called by muse, mutect2, varscan2
- LAMC3 | c.2336dup p.Q781Pfs*7 | Frame Shift Ins (INS) | VAF 60/188 reads (32%) | catalogued as rs765163533; called by mutect2, pindel, varscan2
- LAMC3 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 208/548 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs753468963, COSV100736085; called by muse, mutect2, varscan2
- LHB | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 222/554 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs551522078; called by muse, mutect2
- LHX3 | c.178G>A p.D60N (on ENST00000371748 / NM_178138.6; = p.D65N on NM_014564.5) | Missense Mutation (SNP) | VAF 173/394 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs146027009, COSV65583087; called by muse, mutect2, varscan2
- LHX5 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs748221055, COSV55663654; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 50/143 reads (35%) | catalogued as rs765287063; called by mutect2, varscan2
- LMTK3 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99540831; called by muse, mutect2, varscan2
- LMTK3 | c.363C>T p.D121= | Splice Region (SNP) | VAF 30/74 reads (41%) | catalogued as rs1366358917; called by muse, mutect2, varscan2
- LOXL4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs369940076; called by muse, mutect2
- LRFN3 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 179/435 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs760004767, COSV55818396; called by muse, mutect2, varscan2
- LRIT2 | c.1532dup p.A512Cfs*11 | Frame Shift Ins (INS) | VAF 25/91 reads (27%) | catalogued as rs1307233234; called by mutect2, pindel, varscan2
- LRRC53 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs1348693368; called by muse, mutect2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 68/165 reads (41%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LRRTM1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54443224; called by muse, mutect2, varscan2
- LTB4R2 | c.901C>T p.R301* (on ENST00000528054; = p.R270* on NM_019839.5) | Nonsense Mutation (SNP) | VAF 258/639 reads (40%) | catalogued as rs1338381164; called by muse, mutect2, varscan2
- LTN1 | c.2100del p.V701Sfs*5 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | catalogued as rs753955477; called by mutect2, pindel, varscan2
- LYAR | c.238-2A>G p.X80_splice | Splice Site (SNP) | VAF 50/109 reads (46%) | catalogued as rs752937370; called by muse, mutect2, varscan2
- LYZL6 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs766673424; called by muse, mutect2, varscan2
- MAGEB6 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs775192724, COSV66872018; called by muse, mutect2, varscan2
- MAN1B1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 163/409 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs561918454; called by muse, mutect2, varscan2
- MAN2A2 | c.847dup p.R283Pfs*73 | Frame Shift Ins (INS) | VAF 36/155 reads (23%) | catalogued as rs1343354383; called by mutect2, pindel, varscan2
- MAN2B1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 146/367 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as rs1435717493; called by muse, mutect2, varscan2
- MAN2B2 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as rs373139515; called by muse, mutect2, varscan2
- MANBA | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 156/398 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1467022491; called by muse, mutect2, varscan2
- MAP1B | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs780650498, COSV57103118; called by muse, mutect2, varscan2
- MAP1LC3C | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs982683803; called by muse, mutect2, varscan2
- MBD2 | c.471dup p.G158Rfs*28 | Frame Shift Ins (INS) | VAF 60/158 reads (38%) | catalogued as rs755716804; called by mutect2, varscan2
- MBD3 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 170/381 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV50083256; called by muse, mutect2, varscan2
- MCM5 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs200021712, COSV53346220, COSV99331765; called by muse, mutect2, varscan2
- MDGA1 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1561843973; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDM1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1392139007; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 86/198 reads (43%) | catalogued as rs773080349; called by mutect2, varscan2
- MEGF8 | c.5779C>T p.R1927C (on ENST00000251268 / NM_001271938.2; = p.R1860C on NM_001410.3) | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs368438075; called by muse, mutect2, varscan2
- MEI1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs774663994; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 140/238 reads (59%) | catalogued as rs745891632; called by mutect2, varscan2
- MEX3B | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752952352, COSV61663584; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 144/268 reads (54%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MMP28 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs751685683; called by muse, mutect2, varscan2
- MOB3A | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs199687461; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 86/212 reads (41%) | catalogued as rs755830405; called by mutect2, varscan2
- MPEG1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs200732824; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 97/311 reads (31%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRPS31 | c.739del p.R247Gfs*15 | Frame Shift Del (DEL) | VAF 64/281 reads (23%) | catalogued as COSV100062133; called by mutect2, pindel, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 48/147 reads (33%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MTF1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 137/356 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs773997656; called by muse, mutect2, varscan2
- MTG2 | c.1105G>A p.V369M | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1366793741; called by muse, mutect2, varscan2
- MTM1 | c.963A>T p.L321F | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs782645058; called by muse, mutect2, varscan2
- MTUS2 | c.2595C>A p.S865R | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs866505175; called by muse, mutect2, varscan2
- MUC16 | c.3397del p.M1133* | Frame Shift Del (DEL) | VAF 43/143 reads (30%) | catalogued as rs754876491; called by mutect2, pindel, varscan2
- MUC4 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1363380008; called by muse, varscan2
- MUC5B | c.1982G>A p.C661Y | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762864911; called by muse, mutect2, varscan2
- MUC6 | c.6938C>T p.S2313L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367913682, COSV59962762; called by muse, mutect2, varscan2
- MYB | c.1315C>A p.Q439K | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1476805948; called by muse, mutect2, varscan2
- MYBPC2 | c.2802del p.I937* | Frame Shift Del (DEL) | VAF 119/370 reads (32%) | catalogued as rs1368598634; called by mutect2, pindel, varscan2
- MYH2 | c.4537+1G>A p.X1513_splice | Splice Site (SNP) | VAF 164/397 reads (41%) | catalogued as rs567336764, COSV55435374; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 230/522 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO1C | c.1252G>A p.G418R (on ENST00000648651 / NM_001080779.2; = p.G383R on NM_033375.5) | Missense Mutation (SNP) | VAF 249/547 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764101826; called by muse, mutect2, varscan2
- MYO1F | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as rs373423000; called by muse, varscan2
- MYO3A | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs1339616970; called by muse, mutect2, varscan2
- MYPOP | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs533099876; called by muse, mutect2, varscan2
- NBEA | c.7722G>T p.Q2574H | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.926); catalogued as COSV100081274; called by muse, mutect2
- NCAM1 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.233); catalogued as rs782687432; called by muse, mutect2
- NCAN | c.2621C>T p.T874M | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs148196919; called by muse, mutect2, varscan2
- NCAPH2 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as rs200790371; called by muse, mutect2, varscan2
- NCOA1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as rs749644300, COSV56042370; called by muse, mutect2, varscan2
- NFATC1 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs767841094, COSV53699581; called by muse, mutect2, varscan2
- NFE2 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 194/483 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56457431; called by muse, mutect2, varscan2
- NFE2 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as rs772353922, COSV56456302, COSV56456725; called by muse, mutect2, varscan2
- NFIB | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66621440; called by muse, mutect2, varscan2
- NLGN2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1183734429; called by muse, mutect2, varscan2
- NLGN3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 128/381 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs779160000, COSV62445806; called by muse, mutect2, varscan2
- NOL4L | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs753607764, COSV62889711; called by muse, mutect2, varscan2
- NOTCH3 | c.6233G>A p.R2078Q | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as rs765403158, COSV54628708, COSV54639957; called by muse, varscan2
- NOVA1 | c.1234G>T p.G412* | Nonsense Mutation (SNP) | VAF 93/249 reads (37%) | catalogued as COSV99948426; called by muse, mutect2, varscan2
- NPBWR2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751123142, COSV63900540; called by muse, mutect2, varscan2
- NPHP3 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as rs781537576; called by muse, mutect2, varscan2
- NPPA | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778138090, COSV56738679, COSV56742702; called by muse, mutect2, varscan2
- NR1D1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs373443634, COSV52840970; called by muse, mutect2, varscan2
- NRDE2 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239535998; called by muse, mutect2, varscan2
- NRM | c.187del p.L63Wfs*23 | Frame Shift Del (DEL) | VAF 58/177 reads (33%) | catalogued as rs757081047; called by mutect2, pindel, varscan2
- NT5C1B | c.664C>T p.R222W (on ENST00000359846 / NM_001199086.2; = p.R162W on NM_033253.4) | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV58394824; called by muse, mutect2, varscan2
- NTAN1 | c.890del p.N297Mfs*63 | Frame Shift Del (DEL) | VAF 78/168 reads (46%) | catalogued as rs753931847; called by mutect2, varscan2
- NTRK3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 195/714 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs771206956, COSV58107419; called by muse, mutect2, varscan2
- NUGGC | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.123); catalogued as rs371363580, COSV58439272; called by muse, mutect2, varscan2
- NUP88 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563564141, COSV56702610, COSV56708095; called by muse, mutect2, varscan2
- OBSCN | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 134/329 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV52779154; called by muse, mutect2, varscan2
- ODF3L2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs1363921950; called by muse, mutect2
- ONECUT3 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1309505312; called by muse, mutect2, varscan2
- OPRD1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758135542; called by muse, mutect2, varscan2
- OR10A7 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs751420573, COSV58277829; called by muse, mutect2, varscan2
- OR10K2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs779658726, COSV59221384, COSV59221911; called by muse, mutect2
- OR2D2 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100203819; called by muse, mutect2, varscan2
- OR2M3 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs777056408; called by muse, mutect2, varscan2
- OR4C6 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58605127; called by muse, mutect2, varscan2
- OR4M1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 123/549 reads (22%) | catalogued as rs550760273, COSV60061725; called by muse, mutect2, varscan2
- OR51S1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs560546339, COSV59057342; called by muse, mutect2, varscan2
- OR52I1 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56170317; called by muse, mutect2
- OR5A1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs796662079, COSV57378244; called by muse, mutect2, varscan2
- OR5D18 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 101/204 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs775742265, COSV61737083; called by muse, mutect2, varscan2
- OR6Q1 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56932474; called by muse, mutect2, varscan2
- OR8J3 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1319314823; called by muse, mutect2
- OS9 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57784830, COSV99232899; called by muse, mutect2, varscan2
- OSBP2 | c.1887dup p.S630Lfs*79 | Frame Shift Ins (INS) | VAF 56/168 reads (33%) | catalogued as rs772802379; called by mutect2, varscan2
- OSBPL8 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675854; called by muse, mutect2, varscan2
- OSGEP | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV99248005; called by muse, mutect2, varscan2
- OSM | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs752168515; called by muse, mutect2, varscan2
- OSR1 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 129/286 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs975152724, COSV99693546; called by muse, mutect2, varscan2
- P2RY6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370867718; called by muse, mutect2, varscan2
- P4HA2 | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs776333817; called by muse, mutect2, varscan2
- PAN2 | c.2681A>G p.N894S (on ENST00000425394 / NM_001127460.3; = p.N890S on NM_014871.5) | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312591669; called by muse, mutect2, varscan2
- PANK2 | c.876G>A p.M292I (on ENST00000316562 / NM_153638.3; = p.M1? on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.205); catalogued as rs1320530723; called by muse, mutect2, varscan2
- PAPPA2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs763746287, COSV62778477; called by muse, mutect2, varscan2
- PASD1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1464860454, COSV64855304; called by muse, mutect2, varscan2
- PCDH17 | c.1675del p.A559Rfs*11 | Frame Shift Del (DEL) | VAF 133/543 reads (24%) | catalogued as COSV64977233; called by mutect2, pindel, varscan2
- PCDH8 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393972914; called by muse, mutect2, varscan2
- PCDH8 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as COSV58812644; called by muse, mutect2, varscan2
- PCDHB7 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.83); catalogued as rs200476708; called by muse, mutect2, varscan2
- PCDHGA10 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs201724090; called by muse, mutect2, varscan2
- PCID2 | c.818del p.K273Sfs*4 | Frame Shift Del (DEL) | VAF 67/341 reads (20%) | catalogued as rs760522684; called by mutect2, pindel, varscan2
- PCNX3 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1276445785, COSV63137088; called by muse, mutect2, varscan2
- PDE3A | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs748938027; called by mutect2, varscan2
- PDE6G | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV100148699; called by muse, mutect2, varscan2
- PDGFD | c.640del p.I214Lfs*68 | Frame Shift Del (DEL) | VAF 88/231 reads (38%) | catalogued as rs1333395128; called by mutect2, pindel, varscan2
- PDHA2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54782458; called by muse, mutect2, varscan2
- PDIK1L | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 11/122 reads (9%) | catalogued as COSV65322876; called by muse, mutect2
- PGK1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 129/385 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs782795716; called by muse, mutect2, varscan2
- PHIP | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99244978; called by muse, mutect2, varscan2
- PHLPP1 | c.4717C>T p.R1573W | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs915094142; called by muse, mutect2, varscan2
- PHLPP2 | c.1473G>A p.R491= | Splice Region (SNP) | VAF 88/225 reads (39%) | catalogued as rs764209734; called by muse, mutect2, varscan2
- PIAS1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51031504; called by muse, mutect2, varscan2
- PIGZ | c.1467dup p.T490Dfs*2 | Frame Shift Ins (INS) | VAF 50/132 reads (38%) | catalogued as rs759867499; called by mutect2, varscan2
- PIK3CD | c.1326G>A p.W442* | Nonsense Mutation (SNP) | VAF 172/411 reads (42%) | catalogued as COSV63131381; called by muse, mutect2, varscan2
- PIK3R5 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs747280160, COSV99353171; called by muse, mutect2, varscan2
- PITPNM3 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 192/520 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752293643, COSV52595119; called by muse, mutect2, varscan2
- PIWIL1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs538546986, COSV55350951, COSV99806980; called by muse, mutect2, varscan2
- PKD1 | c.11713-1G>T p.X3905_splice (on ENST00000262304 / NM_001009944.3; = p.X3904_splice on NM_000296.4) | Splice Site (SNP) | VAF 165/345 reads (48%) | catalogued as rs867092741, CS1313912; called by muse, mutect2, varscan2
- PKHD1L1 | c.7321G>A p.V2441I | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533469873; called by muse, mutect2, varscan2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 29/98 reads (30%) | catalogued as rs747170999; called by pindel, varscan2
- PLEKHA7 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753472835; called by muse, mutect2, varscan2
- PLXNA4 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1284623467; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs782076287; called by mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 70/199 reads (35%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PML | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 169/515 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs754797325, COSV51450210; called by muse, mutect2, varscan2
- PNMA3 | c.261del p.W89Gfs*3 | Frame Shift Del (DEL) | VAF 68/164 reads (41%) | catalogued as COSV64722654; called by mutect2, varscan2
- PPARGC1A | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143103266; called by muse, mutect2, varscan2
- PPFIA1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV54134324; called by muse, mutect2, varscan2
- PPFIA3 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61953337; called by muse, mutect2
- PPL | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1384372930; called by muse, mutect2
- PPP1R8 | c.807del p.T270Hfs*34 (on ENST00000311772 / NM_014110.5; = p.T46Hfs*34 on NM_002713.4) | Frame Shift Del (DEL) | VAF 55/164 reads (34%) | catalogued as COSV52579842; called by mutect2, pindel, varscan2
- PPP4R3C | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs910971162; called by muse, mutect2, varscan2
- PPP6R1 | c.2515dup p.Q839Pfs*106 | Frame Shift Ins (INS) | VAF 55/160 reads (34%) | catalogued as rs550637760; called by mutect2, varscan2
- PPWD1 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs765426314; called by muse, mutect2, varscan2
- PROM2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs775648400, COSV58300905; called by muse, mutect2, varscan2
- PRPF38B | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs921122274; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 46/130 reads (35%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRC2C | c.1399C>T p.R467W (on ENST00000367742; = p.R465W on NM_015172.4) | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281668603; called by muse, mutect2, varscan2
- PRSS55 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs765848146; called by muse, mutect2, varscan2
- PTCH1 | c.3715C>T p.R1239W | Missense Mutation (SNP) | VAF 149/385 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs758411912, COSV59499538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCH1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs375628555, COSV59484439; ClinVar: uncertain significance; called by muse, mutect2
- PTCHD4 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs746678221, COSV59780494; called by muse, mutect2, varscan2
- PTOV1 | c.1248dup p.*417Vfs*24 (on ENST00000391842; = p.*417Vfs*77 on NM_017432.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 42/107 reads (39%) | catalogued as rs750392317; called by mutect2, varscan2
- PTPRM | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV59869807; called by muse, mutect2, varscan2
- PTPRS | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 142/395 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs200771602, COSV53637901; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 46/132 reads (35%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- R3HDM4 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1246626354, COSV64293202; called by muse, mutect2, varscan2
- RAD54L | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 235/564 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100914848; called by muse, mutect2, varscan2
- RASAL2 | c.2684G>A p.R895H | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs561944165; called by muse, mutect2, varscan2
- RASSF8 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140972036; called by muse, mutect2, varscan2
- RB1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs776307088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBKS | c.922_923del p.Q308Vfs*38 | Frame Shift Del (DEL) | VAF 54/164 reads (33%) | catalogued as rs781204782; called by pindel, varscan2
- RBM20 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 146/390 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1362458012, COSV101051422; called by muse, mutect2, varscan2
- RBM26 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1186935353; called by muse, mutect2
- RBP3 | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 201/438 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1426209551; called by muse, mutect2, varscan2
- RCSD1 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63261369; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 83/247 reads (34%) | catalogued as COSV100563010; called by mutect2, pindel, varscan2
- REEP5 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1415009098, COSV54842949; called by muse, mutect2, varscan2
- RFPL4B | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV101480729; called by muse, mutect2, varscan2
- RFX6 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756030718, COSV60588807; called by muse, mutect2, varscan2
- RGS20 | c.319del p.L107Cfs*41 | Frame Shift Del (DEL) | VAF 61/158 reads (39%) | catalogued as rs747974681; called by mutect2, pindel, varscan2
- RHOBTB3 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs1395541097; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 60/178 reads (34%) | catalogued as rs760343057; called by mutect2, varscan2
- RNF103 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs966337273; called by muse, mutect2, varscan2
- RNF150 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV60789165, COSV60795272; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 166/274 reads (61%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNFT2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs775396476; called by muse, mutect2, varscan2
- ROBO1 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1263628233; called by muse, mutect2, varscan2
- RP1L1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV66753808; called by muse, mutect2, varscan2
- RSPRY1 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 40/340 reads (12%) | catalogued as rs1329418217; called by muse, mutect2, varscan2
- RTKN | c.467G>T p.G156V (on ENST00000272430 / NM_001015055.2; = p.G143V on NM_033046.2) | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99269526; called by muse, mutect2, varscan2
- RUSF1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1354161627; called by muse, mutect2, varscan2
- RYBP | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1382885623, COSV72180845; called by muse, mutect2, varscan2
- RYR2 | c.13118G>A p.S4373N | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.239); catalogued as COSV63712535; called by muse, mutect2, varscan2
- SALL3 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs906293497, COSV73305790; called by muse, mutect2, varscan2
- SAMD11 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs778084644; called by muse, mutect2, varscan2
- SARDH | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs766900566; called by muse, mutect2, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 151/177 reads (85%) | catalogued as rs761606832; called by mutect2, varscan2
- SBNO2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 129/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323536; called by muse, mutect2, varscan2
- SBSN | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766134876; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 32/73 reads (44%) | catalogued as rs765136101; called by mutect2, varscan2
- SCN8A | c.2543T>A p.L848* | Nonsense Mutation (SNP) | VAF 9/140 reads (6%) | catalogued as rs886043686; called by muse, mutect2
- SCNN1B | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140945152; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SCRN1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs775045104, COSV99620966; called by muse, mutect2, varscan2
- SDHB | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 150/382 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.939); catalogued as rs199948437, COSV64965419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.6475A>G p.R2159G | Missense Mutation (SNP) | VAF 207/468 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1182892356; called by muse, mutect2, varscan2
- SDR9C7 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as rs374434836; called by muse, mutect2, varscan2
- SEBOX | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs782660798; called by muse, mutect2, varscan2
- SEL1L | c.1110del p.G371Vfs*20 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | catalogued as COSV60921783; called by mutect2, varscan2
- SELL | c.1119del p.G374Afs*8 (on ENST00000650983; = p.G361Afs*8 on NM_000655.5) | Frame Shift Del (DEL) | VAF 46/124 reads (37%) | catalogued as rs1421526852; called by pindel, varscan2
- SEMA3F | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50037126; called by muse, mutect2, varscan2
- SEMA6C | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs1266128628, COSV100501692; called by muse, mutect2, varscan2
- SEMG2 | c.493dup p.R165Kfs*9 | Frame Shift Ins (INS) | VAF 44/140 reads (31%) | catalogued as rs1281128483; called by mutect2, pindel, varscan2
- SERPINE1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 161/395 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs867364951; called by muse, mutect2, varscan2
- SF3B2 | c.2625dup p.R876Tfs*16 | Frame Shift Ins (INS) | VAF 31/83 reads (37%) | catalogued as rs759211171; called by mutect2, varscan2
- SHANK2 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs782699631, COSV53589267, COSV99572189; called by muse, mutect2, varscan2
- SHROOM2 | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 134/338 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767591095; called by muse, mutect2, varscan2
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SIGLEC11 | c.1193del p.P398Qfs*4 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs774799128; called by mutect2, pindel, varscan2
- SKOR2 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs1365782843; called by muse, mutect2, varscan2
- SLC16A8 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 120/267 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770955283; called by muse, mutect2, varscan2
- SLC19A1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772742675; called by muse, mutect2, varscan2
- SLC19A3 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 143/371 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as rs200102807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A7 | c.788C>T p.A263V (on ENST00000372585 / NM_153320.2; = p.A261V on NM_006672.3) | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs1346693216, COSV65356238; called by muse, mutect2
- SLC22A7 | c.1106C>T p.S369L (on ENST00000372585 / NM_153320.2; = p.S367L on NM_006672.3) | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs1185252469, COSV99240280; called by muse, mutect2
- SLC30A3 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1162915438; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 97/132 reads (73%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC45A1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775119911; called by muse, mutect2, varscan2
- SLC45A1 | c.2167T>C p.S723P | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1247683382; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC4A3 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.493); catalogued as rs1254650443; called by muse, mutect2, varscan2
- SLC4A7 | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1161458423, COSV55394749; called by muse, mutect2, varscan2
- SLC4A9 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 172/399 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs756572727; called by muse, mutect2, varscan2
- SLCO4C1 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs761404994; called by muse, mutect2, varscan2
- SLIT1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 143/331 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs201085723; called by muse, mutect2, varscan2
- SLIT3 | c.1479C>A p.S493R | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs573099201; called by muse, mutect2, varscan2
- SLK | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs140715399; called by muse, mutect2, varscan2
- SMO | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 168/465 reads (36%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as rs200751953, COSV50835094; called by muse, mutect2, varscan2
- SMPD3 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200140589, COSV54711420; called by muse, mutect2, varscan2
- SNED1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 149/374 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1045964670, COSV60028870; called by muse, mutect2, varscan2
- SNED1 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV60020629; called by muse, mutect2
- SNPH | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); catalogued as rs754975513; called by muse, mutect2, varscan2
- SNX13 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1310054166; called by muse, mutect2, varscan2
- SOGA1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 112/271 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435382042, COSV52914054; called by muse, mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 57/194 reads (29%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SORCS1 | c.1427A>G p.K476R | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1450949270, COSV99549876; called by muse, mutect2, varscan2
- SOS1 | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 133/344 reads (39%) | catalogued as COSV67674007; called by muse, mutect2, varscan2
- SOX5 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58620806; called by muse, mutect2, varscan2
- SOX9 | c.773_774dup p.L259Pfs*21 | Frame Shift Ins (INS) | VAF 65/263 reads (25%) | catalogued as CI098477, COSV55424224; called by mutect2, pindel, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 49/148 reads (33%) | catalogued as rs771765677; called by mutect2, pindel, varscan2
- SPEN | c.10475C>T p.S3492F | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV65270811, COSV65272110; called by muse, mutect2, varscan2
- SPINT2 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 97/242 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as rs1370702137; called by muse, mutect2, varscan2
- SPON2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 99/273 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs916082660; called by muse, mutect2, varscan2
- SPPL2B | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs762401882, COSV101194699; called by muse, mutect2
- SPRING1 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54338575; called by muse, mutect2, varscan2
- SRCIN1 | c.3133C>T p.R1045W (on ENST00000621492; = p.R1011W on NM_025248.3) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1280191131; called by muse, mutect2, varscan2
- SRCIN1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 101/256 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs552981903; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs763130641; called by mutect2, varscan2
- SRRM1 | c.983C>A p.P328Q | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs570634850; called by muse, mutect2, varscan2
- SRRM5 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 188/397 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1318643822, COSV56194441; called by muse, varscan2
- SRSF1 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99365351; called by muse, mutect2, varscan2
- SSR2 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as rs773535812, COSV99828631; called by muse, mutect2, varscan2
- STAG3 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs775128180, COSV99444315; called by muse, mutect2, varscan2
- STAM | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 211/492 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV66351441; called by muse, mutect2, varscan2
- STARD6 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57142002; called by muse, mutect2
- STARD8 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.193); catalogued as COSV52932174; called by muse, mutect2
- STK11IP | c.2956C>G p.P986A | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs748673563; called by muse, mutect2, varscan2
- STON1 | c.793dup p.H265Pfs*20 | Frame Shift Ins (INS) | VAF 25/63 reads (40%) | catalogued as rs747498108; called by mutect2, pindel, varscan2
- STYX | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs554219196; called by muse, mutect2, varscan2
- SUN2 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs749230478, COSV53305031; called by muse, mutect2
- SURF6 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs782465475; called by muse, mutect2, varscan2
- SVEP1 | c.9947C>T p.T3316M | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201866666; called by muse, mutect2, varscan2
- SYCE1L | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1266188546; called by muse, mutect2, varscan2
- SYNGAP1 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144778033; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNM | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 337/557 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1472634299; called by muse, mutect2, varscan2
- TAB1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 234/399 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs373883129; called by muse, mutect2, varscan2
- TACSTD2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 157/414 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV64667085; called by muse, mutect2, varscan2
- TAF4 | c.2086G>A p.V696M | Missense Mutation (SNP) | VAF 85/163 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767742516, COSV53344057; called by muse, mutect2, varscan2
- TAF6 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59842516; called by muse, mutect2, varscan2
- TANC1 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs759435249, COSV55084015, COSV55098286; called by muse, mutect2, varscan2
- TAOK3 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1019601490; called by muse, mutect2, varscan2
- TARS3 | c.1271dup p.L425Pfs*9 | Frame Shift Ins (INS) | VAF 46/94 reads (49%) | catalogued as rs1207173849; called by mutect2, pindel, varscan2
- TASP1 | c.1095A>C p.L365= | Splice Region (SNP) | VAF 44/105 reads (42%) | catalogued as rs747166003; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 38/111 reads (34%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D32 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99251569; called by muse, mutect2, varscan2
- TBXT | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 165/382 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51617239; called by muse, mutect2, varscan2
- TCF19 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565850915; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 47/122 reads (39%) | catalogued as rs748021112; called by mutect2, varscan2
- TCTE1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs537656871, COSV104424281; called by muse, mutect2, varscan2
- TCTE1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151164597, COSV65255558; called by muse, mutect2, varscan2
- TDP1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 220/546 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs113531329; called by muse, mutect2, varscan2
- TDRD6 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs1351763540, COSV60177012; called by muse, mutect2, varscan2
- TECPR1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457116947, COSV65784318; called by muse, mutect2, varscan2
- TENM1 | c.4600T>C p.Y1534H | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64431250; called by muse, mutect2, varscan2
- TENM3 | c.5548G>A p.V1850M | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as rs748357813; called by muse, mutect2, varscan2
- TENM4 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.04); catalogued as rs1481708121; called by muse, mutect2, varscan2
- TET2 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 227/566 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs4145756, COSV54419646; called by muse, mutect2, varscan2
- TG | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as rs759789389, COSV99600793; called by muse, mutect2, varscan2
- TGIF2LX | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 144/376 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs773693755, COSV99383199; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | catalogued as rs746975641; called by mutect2, varscan2
- TIAM1 | c.3860del p.K1287Rfs*29 | Frame Shift Del (DEL) | VAF 56/192 reads (29%) | catalogued as COSV99734939; called by pindel, varscan2
- TIGD3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 174/442 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV52887847; called by muse, mutect2, varscan2
- TKTL1 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs936805186; called by muse, mutect2, varscan2
- TLCD3B | c.28dup p.V10Gfs*59 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | catalogued as rs780301705; called by mutect2, varscan2
- TLE3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as rs774554797, COSV58168716; called by muse, varscan2
- TMCC3 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as rs1303417409; called by muse, mutect2, varscan2
- TMEM121B | c.1486C>A p.L496I | Missense Mutation (SNP) | VAF 166/472 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV58898378; called by muse, mutect2, varscan2
- TMEM132D | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs144267550, COSV67160505, COSV67160591, COSV67162685; called by muse, mutect2, varscan2
- TMEM145 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as rs1467739554, COSV52090596, COSV52095927; called by muse, mutect2, varscan2
- TMEM260 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as rs955315296; called by muse, varscan2
- TMEM267 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 169/393 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67992629; called by muse, mutect2, varscan2
- TMEM8B | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.113); catalogued as COSV65075677; called by muse, mutect2, varscan2
- TMPRSS7 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 92/273 reads (34%) | catalogued as rs753285417; called by muse, mutect2, varscan2
- TNFAIP1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 204/521 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs373733645; called by muse, mutect2, varscan2
- TNIP1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340667932; called by muse, varscan2
- TNK2 | c.1482del p.D495Tfs*3 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as rs750898925, COSV100361004; called by mutect2, pindel, varscan2
- TOP2B | c.4321del p.S1441Vfs*41 (on ENST00000264331 / NM_001330700.2; = p.S1436Vfs*41 on NM_001068.3) | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs1293862281; called by mutect2, pindel, varscan2
- TOX2 | c.730C>T p.P244S (on ENST00000358131 / NM_001098798.2; = p.P193S on NM_032883.3) | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs1186188793; called by muse, mutect2, varscan2
- TP73 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs770656238; called by muse, mutect2, varscan2
- TPP2 | c.3394G>A p.A1132T | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs1329723822; called by muse, mutect2, varscan2
- TRAF5 | c.1368del p.S457Hfs*26 | Frame Shift Del (DEL) | VAF 77/223 reads (35%) | catalogued as COSV99807703; called by mutect2, pindel, varscan2
- TRAF7 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 175/429 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs751318317, COSV58218349; called by muse, mutect2, varscan2
- TRAFD1 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as rs115008525; called by muse, mutect2, varscan2
- TRAPPC11 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs577423330, COSV58216838; called by muse, mutect2, varscan2
- TRIM41 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 119/294 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as rs753810828; called by muse, mutect2, varscan2
- TRIM67 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 128/340 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100792225; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 72/138 reads (52%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIO | c.8228C>T p.T2743M | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs139314793; called by muse, mutect2
- TRIP12 | c.4417C>A p.L1473I | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52259212; called by muse, mutect2, varscan2
- TRMT12 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV60776624; called by muse, mutect2, varscan2
- TRPM2 | c.3820C>T p.P1274S | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV55976806; called by muse, mutect2, varscan2
- TRPM4 | c.3462G>A p.K1154= | Splice Region (SNP) | VAF 204/496 reads (41%) | catalogued as rs771732356; called by muse, mutect2, varscan2
- TRRAP | c.4802G>A p.R1601Q (on ENST00000359863 / NM_001244580.1; = p.R1583Q on NM_003496.3) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as rs782247298; called by muse, mutect2, varscan2
- TTBK2 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 184/305 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs371341038, COSV99141078; called by muse, mutect2, varscan2
- TTC27 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200122950; called by muse, mutect2, varscan2
- TTN | c.61519G>A p.A20507T (on ENST00000591111; = p.A13083T on NM_003319.4) | Missense Mutation (SNP) | VAF 133/334 reads (40%) | PolyPhen benign (0.232); catalogued as rs794727433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.2506G>A p.G836S (on ENST00000591111; = p.G790S on NM_003319.4) | Missense Mutation (SNP) | VAF 69/174 reads (40%) | PolyPhen probably damaging (0.962); catalogued as rs751157908, COSV59988553, COSV60007599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP4 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV65577457; called by muse, mutect2, varscan2
- TYR | c.1487T>C p.V496A | Missense Mutation (SNP) | VAF 149/396 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1307528596; called by muse, mutect2, varscan2
- UBQLN3 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs756923573; called by muse, mutect2, varscan2
- UFL1 | c.1978del p.R660Gfs*17 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | catalogued as rs750472217; called by mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 84/179 reads (47%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UNC13D | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 125/324 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776737156, CM112830, COSV52884054; called by muse, mutect2, varscan2
- UNC5B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs753370821; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 29/76 reads (38%) | catalogued as rs760213136; called by mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.15355C>T p.R5119W | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs767137840, COSV56391560; called by muse, mutect2, varscan2
- USP13 | c.1896dup p.I633Hfs*5 | Frame Shift Ins (INS) | VAF 40/128 reads (31%) | catalogued as rs780272979; called by mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 60/155 reads (39%) | catalogued as rs749830910; called by mutect2, varscan2
- USP35 | c.2290C>A p.L764M | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as rs375971115; called by muse, mutect2, varscan2
- UTP14C | c.311dup p.Q105Afs*4 | Frame Shift Ins (INS) | VAF 236/974 reads (24%) | catalogued as rs1175995992; called by mutect2, varscan2
- VASP | c.551del p.P184Hfs*84 | Frame Shift Del (DEL) | VAF 47/118 reads (40%) | catalogued as rs762759767; called by mutect2, varscan2
- VLDLR | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 182/444 reads (41%) | catalogued as rs141396971; called by muse, mutect2, varscan2
- VPS13B | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs773472945, COSV62020498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765547105, COSV62145591; called by muse, mutect2, varscan2
- VSTM2L | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1451937759; called by muse, mutect2, varscan2
- WDR27 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs752929948; called by muse, mutect2, varscan2
- WDR59 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50936248; called by muse, mutect2
- WDR70 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs765801273, COSV54284222; called by muse, mutect2, varscan2
- WDR81 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as rs1439677993, COSV58486177; called by muse, mutect2, varscan2
- WIPF2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765209297, COSV100063525, COSV100063743; called by muse, mutect2, varscan2
- WNK1 | c.2263G>A p.V755M (on ENST00000315939 / NM_018979.4; = p.V754M on NM_014823.3) | Missense Mutation (SNP) | VAF 156/339 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as rs1444380006; called by muse, mutect2, varscan2
- WTIP | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV54328243; called by muse, mutect2, varscan2
- XIRP2 | c.5316del p.D1773Mfs*5 (on ENST00000628543; = p.D1948Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 53/128 reads (41%) | catalogued as rs760810271; called by mutect2, pindel, varscan2
- XPO4 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 46/207 reads (22%) | catalogued as COSV99688362; called by muse, mutect2, varscan2
- XYLT2 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50017497; called by muse, mutect2, varscan2
- YY1AP1 | c.2279C>T p.P760L (on ENST00000295566 / NM_139118.2; = p.P703L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/426 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.969); catalogued as rs372287277; called by muse, mutect2, varscan2
- ZBTB3 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as rs866849906; called by muse, mutect2, varscan2
- ZC3H12C | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs769365245, COSV53713163; called by muse, mutect2
- ZFHX3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs779915209; called by muse, mutect2, varscan2
- ZIC3 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54975418; called by muse, mutect2
- ZMIZ2 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1405506739, COSV54807197; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 87/163 reads (53%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF142 | c.2030G>A p.R677Q (on ENST00000411696 / NM_001379660.1; = p.R477Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs759292993, COSV101376949; called by muse, mutect2, varscan2
- ZNF16 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs752265890, COSV52763616; called by muse, mutect2, varscan2
- ZNF174 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as COSV51902619; called by muse, mutect2, varscan2
- ZNF180 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs201078626; called by muse, mutect2, varscan2
- ZNF180 | c.208-3del | Splice Region (DEL) | VAF 61/205 reads (30%) | catalogued as rs1568425500; called by mutect2, pindel, varscan2
- ZNF217 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 168/400 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100184238, COSV56600266; called by muse, mutect2, varscan2
- ZNF292 | c.7032G>T p.K2344N | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.941); catalogued as COSV60536211; called by muse, mutect2, varscan2
- ZNF346 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99993213; called by muse, mutect2, varscan2
- ZNF439 | c.972dup p.L325Tfs*3 | Frame Shift Ins (INS) | VAF 83/245 reads (34%) | catalogued as rs1313557565; called by mutect2, pindel, varscan2
- ZNF45 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV54192846; called by mutect2, varscan2
- ZNF486 | c.607del p.I203Lfs*28 | Frame Shift Del (DEL) | VAF 50/139 reads (36%) | catalogued as rs1555718177; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 36/120 reads (30%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF572 | c.18dup p.L7Tfs*7 | Frame Shift Ins (INS) | VAF 48/128 reads (38%) | catalogued as rs769734933; called by mutect2, varscan2
- ZNF592 | c.1879_1881del p.F627del | In Frame Del (DEL) | VAF 387/775 reads (50%) | catalogued as rs1250559095; called by pindel, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 158/275 reads (57%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF629 | c.377del p.P126Qfs*208 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | catalogued as COSV52698686; called by mutect2, pindel, varscan2
- ZNF672 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as rs1365618651; called by muse, mutect2, varscan2
- ZNF684 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.299); catalogued as COSV65519756; called by muse, mutect2, varscan2
1,501 further variants in this file (730 protein-altering or splice-affecting, 455 silent, 316 other) are not listed here.
